Surgical pathology report (de-identified scan), TCGA case TCGA-B9-A44B, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site UNC, specimen TCGA-B9-A44B-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Left kidney, resection

1CD-0-3
renal cell carcinoma, papillary
8260/3
Site: Kidney, NOS
C64.9
8-23-12
RD

Histologic tumor type/subtype: Papillary renal cell carcinoma, type 2

Sarcomatoid features: Not identified

Histologic grade (if applicable): Fuhrman Grade 3 of 4

Tumor size (greatest dimension): 12 cm

Tumor focality: Unifocal

Extent of tumor invasion (if present specify if macroscopic or microscopic):

Capsular invasion: Involved by tumor (microscopic)

Perirenal adipose tissue: Not involved

Gerota' s fascia: Not involved

Renal sinus: Involved by tumor (macroscopic)

Major veins (renal vein or segmental branches, : Involved by tumor (macro and microscopic)

Ureter: Involved by tumor (macro and microscopic)

Venous (large vessel): Involved by tumor, extensive

Lymphatic (small vessel): Involved by tumor

Histologic assessment of surgical margins:

Gerota' s fascia (nephrectomy): Negative for malignancy

Renal vein (nephrectomy): Positive for tumor

Renal artery (nephrectomy): Negative for malignancy

Ureter (nephrectomy): Negative for malignancy

Adrenal gland: Negative for malignancy

Lymph nodes: Not received

Other significant findings: Perineural invasion with involvement of ganglion (A1)

Renal cortical adenoma, 1 mm in greatest dimension (A11)

AJCC Staging: pT3b pNX

This staging information is based on information available at

[page 2 of 4]
the time of this report, and is subject to change pending clinical review and additional information.

B: Tumor thrombus, resection

- Papillary renal cell carcinoma, type 2

C: Right renal vein margin, biopsy

- Positive for papillary renal cell carcinoma, type 2

Clinical History:

year-old with a left renal mass.

Gross Description:

Received are three appropriately labeled containers.

Container A:

Specimen fixation: formalin

Type of specimen: radical nephrectomy

Side of specimen: left

Size and weight of specimen: 25 cm x 14 cm x 9 cm, 1,395 grams

Orientation: The external perinephric fat is inked blue.

Presence/absence of adrenal gland: present

Tumor site: involves the majority of the kidney (upper and lower poles, cortex and medulla)

Tumor description: yellow, soft, hemorrhagic, multifocal, sharp borders

Tumor size: 12 cm x 9 cm x 9 cm

Presence/absence of multicentricity: absent

Confinement/non-confinement to the kidney: appears confined

Extent of invasion:

Perirenal adipose tissue: tumor does not grossly involve

[page 3 of 4]
Gerota' s fascia: not grossly involved

Renal vein: suspicious for involvement, grossly there is a large soft mass protruding through the lumen of the vein, clot versus tumor

Ureter: suspicious for involvement

Renal Sinus: involved

Pelvicaliceal: involved

Adrenal: does not grossly involve

Other organs: not present

Surgical margins:

Perirenal adipose tissue: negative, widely free

Renal vein: potentially involved, tumor approaches within 0.5 cm of margin

Renal artery: negative, tumor within 1 cm of margin

Ureter: negative, tumor within 0.6 cm of margin

Description of kidney away from tumor: tan, cystic in some areas

Hilar lymph nodes: none identified

Other significant findings: There is a potential clot located in the renal vein (clot versus tumor).

Tissue submitted for special investigations: tumor

Digital picture: not taken

Block summary:

- A1 - renal vein with clot versus tumor (non-marginal)
- A2 - renal artery, renal vein, ureter margins, en face
- A3,A4 - ureter suspicious for tumor involvement (non-marginal)
- A5 - sections of renal capsule, suspicious for tumor (non-marginal)
- A6,A7 - tumor (non-marginal)
- A8 - tumor at pelvis

[page 4 of 4]
A9,A10 - blue inked perinephric fat margins (not grossly involved)

A11 - remnant of more normal appearing kidney

A12 - representative sections of uninvolved adrenal gland

Container B is additionally labeled "tumor thrombus." It holds a gray/black soft tissue fragment measuring 1.0 x 0.5 x 0.5 cm.
(Block B1,

Container C is additionally labeled "right renal vein margin."
It holds a fragment of renal vein measuring 1.8 x 1.2 x 1.0 cm.
Staples are removed. The fragment is sectioned and placed into block C1,

Source: NCI Genomic Data Commons file 3062bca1-1989-423b-90c8-c000335a6922 (TCGA-B9-A44B.2D9DFA52-DFC5-4F50-9D77-523C5DEDB049.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).